Somatic mutation profile of tumor specimen C3L-01749-01 (aliquot CPT0127700006) from CPTAC case C3L-01749, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 54.7 years (19,978 days).
Specimen C3L-01749-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1455d58-c801-41ad-b75e-7973ca5f6df3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01749-72 (Blood Derived Normal), aliquot CPT0127770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74efc1a1-19a1-4273-b647-ea768f022e7d

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, Intron 2, 5'UTR 1, RNA 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 51/128 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 42/247 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- CXXC4 | c.1084G>T p.A362S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.19); catalogued as COSV67296585; called by muse, mutect2, varscan2
- MYO6 | c.1216G>A p.V406I | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs377562418; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHB8 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as COSV50753684; called by muse, mutect2, varscan2
- PPP2R1A | c.771G>T p.W257C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV59043009, COSV59045350; called by muse, mutect2, varscan2
- STAB1 | c.5386C>T p.R1796W | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs201109781; called by muse, mutect2, varscan2
- ANGPTL4 | c.1181C>G p.T394S | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- DMD | c.9491A>C p.E3164A | Missense Mutation (SNP) | VAF 55/368 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- DPYSL2 | c.221C>T p.T74I | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EFR3A | c.1194G>T p.R398S | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- ENOX2 | c.565G>A p.G189S (on ENST00000338144 / NM_001382520.1; = p.G160S on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FOXP1 | c.351G>C p.Q117H | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- FTSJ1 | c.583G>C p.V195L | Missense Mutation (SNP) | VAF 67/424 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- MEP1B | c.1693C>G p.H565D | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- MMP23B | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 51/307 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OPHN1 | c.1871C>A p.T624N | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PGM3 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTBN5 | c.4500G>T p.R1500= | Splice Region (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- TCOF1 | c.704C>G p.A235G | Missense Mutation (SNP) | VAF 53/337 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TRIP12 | c.4833C>G p.S1611R | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACOT13 | c.168C>T p.H56= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as rs545035137, COSV57764931, COSV57765305; called by muse, mutect2, varscan2
- DLC1 | c.666G>A p.E222= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs954964043, COSV52289766; called by muse, mutect2, varscan2
- LOXHD1 | c.3591C>A p.I1197= | Silent (SNP) | VAF 21/139 reads (15%) | called by muse, mutect2, varscan2
- SYMPK | c.3333G>A p.A1111= | Silent (SNP) | VAF 22/151 reads (15%) | catalogued as rs747629960; called by muse, mutect2, varscan2
- TLK2 | c.12A>G p.E4= | Silent (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- MAX | c.37-16T>C | Intron (SNP) | VAF 42/232 reads (18%) | catalogued as rs538042707, COSV52418316; called by mutect2, varscan2
- MYT1L | c.55+15C>T | Intron (SNP) | VAF 34/212 reads (16%) | called by muse, mutect2, varscan2
- NXPH3 | c.*2521C>T | 3'UTR (SNP) | VAF 20/120 reads (17%) | catalogued as rs1290709095; called by muse, mutect2, varscan2
- OVCH1-AS1 | n.253C>T | RNA (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- STIP1 | c.-27C>G | 5'UTR (SNP) | VAF 47/293 reads (16%) | catalogued as rs1028231435; called by muse, mutect2, varscan2
